Somatic mutation profile of tumor specimen TARGET-10-PATEHZ-03A (aliquot TARGET-10-PATEHZ-03A-01D) from TARGET case TARGET-10-PATEHZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,198 days).
Specimen TARGET-10-PATEHZ-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b648513c-da1f-474c-99f5-902edf195c7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATEHZ-10A (Blood Derived Normal), aliquot TARGET-10-PATEHZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e871d588-c86f-4b5a-84a1-665c104e4171

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, Silent 2, 3'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NIM1K | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58141003; called by muse, mutect2, varscan2
- OGDHL | c.1124C>G p.T375R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV65101968; called by muse, mutect2, varscan2
- PLXNA2 | c.4781T>C p.V1594A | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV65439937; called by muse, mutect2, varscan2
- PNLIP | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV65040228; called by muse, mutect2, varscan2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- USP7 | c.1018_1019insAGAAC p.R340Qfs*15 | Frame Shift Ins (INS) | VAF 20/39 reads (51%) | catalogued as COSV100784179, COSV61213366, COSV61214171; called by mutect2, pindel*, varscan2*
- STMN2 | c.495G>A p.A165= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs772336347, COSV55220138; called by muse, mutect2, varscan2
- ZIK1 | c.27G>A p.P9= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV56737262; called by muse, mutect2, varscan2
- LRRC41 | c.200-38A>G | Intron (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- MLIP | c.613-11888C>T | Intron (SNP) | VAF 58/125 reads (46%) | called by muse, mutect2, varscan2
- OOSP3 | chr11:59898256 C>T | 3'Flank (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- TP53I11 | c.*6C>T | 3'UTR (SNP) | VAF 35/81 reads (43%) | catalogued as rs370800591, COSV100370959; called by muse, mutect2, varscan2
